Gene-level copy-number profile of tumor specimen HCM-SANG-0272-C20-01B from HCMI case HCM-SANG-0272-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0272-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a3d5d41-2a8a-4364-8701-2bc2b5029dd7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0272-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/1bbd128f-f01c-4e4d-9fd8-f115a65a8717

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 363; copy number 2: 11,364; copy number 3: 2,447; copy number 4: 33,496; copy number 5: 5,118; copy number 6: 4,813; copy number 7: 622; copy number 8: 71; copy number 9: 68; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,691,262–49,691,523, 1 gene (within-gene range 0–2): AL390023.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr14:83,048,579–84,177,088, 7 genes: RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, MTND4P33, MTND5P35, MTCYBP27.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–2): MIR1233-2.
- chr15:77,041,404–77,420,144, 7 genes (within-gene range 0–2): TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 72 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes, copy number 10: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr8:66,870,749–67,056,604, 6 genes, copy number 9 (within-gene range 6–9): MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 10: AL590623.1.
- chr20:16,272,104–18,766,644, 62 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 349. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
